CCDI case PBCNJT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/73722103-b50a-430b-9788-e5800ac75104

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 0.1 years (40 days).

Biospecimens (2 samples)
- Sample 0DVZ0Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ1M: Tissue type: Tumor; Specimen type: Solid Tissue.
